Somatic mutation profile of tumor specimen MBCProject_0351_T1_WES (aliquot MBCProject_0351_T1_WES_1) from CMI case MBCProject_0351, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 46.9 years (17,142 days).
Specimen MBCProject_0351_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1e8c066-ff56-4b42-842c-b117ed14fa4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0351_SALIVA (Saliva), aliquot MBCProject_0351_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5b94595-6879-4a4c-b3c6-758df69b525c

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 1, 5'Flank 1, In Frame Ins 1, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8624A>G p.N2875S | Missense Mutation (SNP) | VAF 56/80 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782451, CD120363, CM102244, COSV53726848, COSV53730217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 104/206 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DOCK11 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as rs367556830; called by muse, mutect2, varscan2
- KRTAP5-7 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 155/221 reads (70%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.146); catalogued as rs1266330239, COSV68325185, COSV68325578; called by muse, mutect2, varscan2
- LMOD1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770962428, COSV66172823; called by muse, varscan2
- NELL1 | c.5C>A p.P2Q | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.795); catalogued as COSV54297731, COSV54315240; called by muse, mutect2, varscan2
- NLRP7 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.799); catalogued as rs771101644, COSV60171092; called by muse, mutect2, varscan2
- SMIM9 | c.272+1G>A p.X91_splice | Splice Site (SNP) | VAF 36/77 reads (47%) | catalogued as rs782225641; called by muse, mutect2
- TRIB2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 31/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50232187; called by muse, mutect2
- ZFYVE1 | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59611547; called by muse, mutect2, varscan2
- ADCY7 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- BCKDHB | c.18_20dup p.A8dup | In Frame Ins (INS) | VAF 36/64 reads (56%) | called by mutect2, varscan2
- CFAP65 | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- EHD2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- MED23 | c.1013T>G p.L338R | Missense Mutation (SNP) | VAF 173/282 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2M4 | c.286_287del p.G96Lfs*15 | Frame Shift Del (DEL) | VAF 48/213 reads (23%) | called by mutect2, pindel, varscan2
- CHSY3 | c.336G>T p.R112= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1458890676, COSV100519487; called by muse, mutect2, varscan2
- DYNC2H1 | c.12444C>T p.A4148= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- LTBP2 | c.939C>T p.N313= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs141536587; called by muse, mutect2, varscan2
- VCX | c.582G>A p.P194= | Silent (SNP) | VAF 55/318 reads (17%) | catalogued as rs764316338, COSV58232163, COSV58233998; called by muse, mutect2, varscan2
- C8orf87 | n.66C>A | RNA (SNP) | VAF 117/225 reads (52%) | called by muse, mutect2, varscan2
- NDUFC2 | c.*27C>T | 3'UTR (SNP) | VAF 116/1972 reads (6%) | called by muse, mutect2
- WWC2 | chr4:183098507 G>T | 5'Flank (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
